Gene-level copy-number profile of tumor specimen TCGA-V5-AASV-01A from TCGA case TCGA-V5-AASV, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 67.2 years (24,559 days).
Specimen TCGA-V5-AASV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.aa10c214-627a-41a0-ad53-a674d6f0f55d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-V5-AASV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/13070057-3517-4b4d-b40e-185ea95805d8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 59; copy number 1: 3,138; copy number 2: 39,055; copy number 3: 17,410; copy number 4: 2; copy number 6: 147.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-V5-AASV-01A-11D-A386-01): tumor purity 0.74, ploidy 2.27, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 59 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:233,917,373–234,019,522, 1 gene (within-gene range 0–1): TRPM8.
- chr2:233,977,872–236,507,535, 33 genes (within-gene range 0–2): AC005538.3, SPP2, AC006037.2, AC006037.1, AC122134.1, RPS20P12, AC097713.2, AC097713.1, LINC01891, HSPE1P9, ARL4C, LINC01173, AC104394.1, AC010148.1, SH3BP4, AC114814.1, CEP19P1, AC114814.2, AGAP1, AGAP1-IT1, AC064874.1, TMSB10P1, RNU7-127P, RN7SL204P, Y_RNA, GBX2, AC019068.1, ASB18, RNU1-31P, IQCA1, AC093915.1, IQCA1-AS1, RPL3P5.
- chr4:186,587,794–187,748,199, 17 genes: FAT1, AC107050.1, AC108865.1, AC108865.2, MRPS36P2, AC110772.1, AC110772.2, AC108046.1, LINC02374, AC097652.1, LINC02514, LINC02515, AC093763.2, AC093763.1, LINC02492, AC097521.1, ADAM20P3.
- chr8:3,700,492–3,700,628, 1 gene: RNA5SP251.
- chr17:3,923,870–4,187,310, 5 genes (within-gene range 0–1): ATP2A3, LINC01975, ZZEF1, RNA5SP434, CYB5D2.
- chr17:4,163,910–4,186,424, 2 genes: AC087292.1, Y_RNA.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 147 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:165,957,188–175,463,180, 147 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 757. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
